Gene-level copy-number profile of tumor specimen TCGA-DK-A6B2-01A from TCGA case TCGA-DK-A6B2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 70.2 years (25,625 days).
Specimen TCGA-DK-A6B2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.54f4840a-4792-4058-b090-5e9063bc5f44.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A6B2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8344a332-5887-4c0b-b7a9-98c9e53edf52

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 25; copy number 2: 11,936; copy number 3: 26,463; copy number 4: 12,136; copy number 5: 4,882; copy number 6: 2,609; copy number 7: 696; copy number 8: 129; copy number 9: 606; copy number 11: 89; copy number 13: 3; copy number 15: 164; copy number 16: 45; copy number 19: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A6B2-01A-11D-A30D-01): tumor purity 0.49, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,756 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–153,986,358, 471 genes, copy number 9 (broad region; genes not listed).
- chr1:160,485,030–174,995,308, 342 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr3:12,287,368–12,561,059, 6 genes, copy number 8 (within-gene range 3–8): PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS.
- chr3:161,496,808–173,336,965, 143 genes, copy number 7 (broad region; genes not listed).
- chr8:46,028,804–75,034,558, 451 genes, copy number 7–19 (broad region; genes not listed).
- chr12:56,822,985–58,920,504, 83 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr12:63,822,021–73,208,317, 193 genes, copy number 7–15 (broad region; genes not listed).
- chr12:78,052,181–84,939,668, 67 genes, copy number 8–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
